Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81N, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81N-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date report:

Material: right adrenal

There is a 4.2x3.2x0.4cm measuring tan tumor with central necrosis and close proximity to the border of resection. Here, laceration of the specimen is present.

The appearance is line with the clinical diagnosis of a pheochromocytoma.

Immunohistochemically, the tumor strongly stains positive for synaptophysin, with weak staining for chromogranin. S100 identifies the rare sustentacular cells. A proliferation index of <1% is determined with Ki67.

Final diagnosis: pheochromocytoma

Translated by:

ICD-O-3
Pheochromocytoma NOS 8700/0
Site: @ Adrenal gland NOS 874.0
JW 10/17/13

Source: NCI Genomic Data Commons file 15b80094-08c1-4e27-bfbd-c553bb243d76 (TCGA-WB-A81N.3ACF2CF1-F114-4A3F-82D7-25E98465107E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).